Gene-level copy-number profile of tumor specimen TCGA-64-5779-01A from TCGA case TCGA-64-5779, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.1 years (22,305 days).
Specimen TCGA-64-5779-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7f560af0-720e-4316-b902-bab72e6b53a5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-64-5779-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b3df97fe-66aa-4f44-8f69-2587ad5b5442

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 722; copy number 2: 26,915; copy number 3: 17,246; copy number 4: 10,877; copy number 5: 692; copy number 6: 2,118; copy number 7: 77; copy number 8: 101; copy number 9: 86; copy number 10: 329; copy number 11: 60; copy number 12: 150; copy number 13: 146; copy number 14: 53; copy number 15: 14; copy number 16: 33; copy number 17: 41; copy number 18: 8; copy number 19: 1; copy number 20: 82; copy number 21: 7; copy number 22: 21; copy number 23: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-64-5779-01A-01D-1624-01): tumor purity 0.44, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,047 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,630,335–40,692,066, 132 genes, copy number 6–23 (broad region; genes not listed).
- chr1:42,463,221–42,657,190, 5 genes, copy number 6 (within-gene range 3–6): CCDC30, RPS3AP11, TMSB4XP1, RNU6-536P, AL445669.1.
- chr1:150,508,062–154,155,116, 220 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:42,494,569–48,776,517, 131 genes, copy number 9–16 (within-gene range 3–16) (broad region; genes not listed).
- chr2:94,725,674–114,420,302, 494 genes, copy number 6–14 (broad region; genes not listed).
- chr2:161,424,332–170,120,098, 93 genes, copy number 9–20 (within-gene range 4–20) (broad region; genes not listed).
- chr7:54,676,217–54,812,727, 4 genes, copy number 6: AC011228.3, AC011228.2, SEC61G, SEC61G-DT.
- chr8:150,584–2,623,382, 53 genes, copy number 5–6: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1.
- chr8:37,405,439–145,066,685, 1,703 genes, copy number 5–6 (broad region; genes not listed).
- chr11:65,120,630–66,563,334, 118 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:26,443,090–42,989,483, 235 genes, copy number 9–20 (within-gene range 2–20) (broad region; genes not listed).
- chr14:79,072,132–79,074,767, 1 gene, copy number 5: AC026888.1.
- chr17:13,299,184–13,306,771, 1 gene, copy number 14: LINC02093.
- chr18:20,946,906–76,972,901, 795 genes, copy number 5–22 (within-gene range 4–22) (broad region; genes not listed).
- chr20:44,694,892–44,752,313, 4 genes, copy number 5: KCNK15-AS1, CCN5, KCNK15, AL118522.1.
- chr21:16,574,718–17,660,384, 18 genes, copy number 5: AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1.
- chr21:22,436,290–23,490,724, 14 genes, copy number 8–19: MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1.
- chr21:24,840,550–25,057,746, 1 gene, copy number 8 (within-gene range 3–8): LINC01692.
- chr21:24,938,431–25,772,460, 23 genes, copy number 8: AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2.
- chr21:25,928,754–25,952,614, 2 genes, copy number 8: AP001442.1, RNU6-123P.

Autosomal genes at a single copy (total copy number 1): 710. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
